Somatic mutation profile of tumor specimen C3N-00572-04 (aliquot CPT0015410009) from CPTAC case C3N-00572, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G2; Age at diagnosis: 48.6 years (17,745 days).
Specimen C3N-00572-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fb9937de-f267-4a7e-81e0-8e1a9b01e9f6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00572-71 (Blood Derived Normal), aliquot CPT0015440002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6c9312f9-6df5-4259-9774-4d7b89a01747

The open-access MAF lists 35 somatic variants for this specimen: 23 protein-altering or splice-affecting, 8 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 8, Nonsense Mutation 3, 5'Flank 2, 5'UTR 1, 3'Flank 1, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACVR1B | c.1381C>T p.Q461* | Nonsense Mutation (SNP) | VAF 36/239 reads (15%) | catalogued as COSV57776537; called by muse, mutect2, varscan2
- AMER1 | c.1564G>A p.D522N | Missense Mutation (SNP) | VAF 8/192 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as COSV100367170, COSV57670802; called by muse, mutect2
- ASAP2 | c.1681G>T p.G561* | Nonsense Mutation (SNP) | VAF 12/189 reads (6%) | catalogued as COSV99855680; called by muse, mutect2
- FEN1 | c.1052C>T p.S351F | Missense Mutation (SNP) | VAF 68/380 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.254); catalogued as rs774266785, COSV99952921; called by muse, mutect2, varscan2
- HENMT1 | c.40G>A p.G14S | Missense Mutation (SNP) | VAF 52/260 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.012); catalogued as rs760699119; called by muse, varscan2
- HID1 | c.1040G>T p.R347L | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.107); catalogued as COSV100585963, COSV100586117; called by muse, mutect2, varscan2
- HLA-DRB5 | c.440C>G p.S147C | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs184544272; called by muse, varscan2
- IHO1 | c.184G>A p.G62S | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.415); catalogued as rs770163003; called by muse, mutect2, varscan2
- SH3TC1 | c.319C>T p.R107W | Missense Mutation (SNP) | VAF 16/205 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752988270, COSV99795267; called by muse, mutect2
- TMEM132E | c.2431G>A p.A811T (on ENST00000321639; = p.A901T on NM_001304438.2) | Missense Mutation (SNP) | VAF 35/221 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58698849; called by muse, mutect2, varscan2
- TP53 | c.1022T>A p.F341Y | Missense Mutation (SNP) | VAF 46/273 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); catalogued as COSV52788709, COSV53575906; called by muse, mutect2, varscan2
- USPL1 | c.593G>A p.R198K | Missense Mutation (SNP) | VAF 42/323 reads (13%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs752693332; called by muse, mutect2, varscan2
- AGAP2 | c.602G>C p.G201A | Missense Mutation (SNP) | VAF 13/212 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.878); called by muse, mutect2
- ARHGAP36 | c.92dup p.L31Ffs*27 | Frame Shift Ins (INS) | VAF 46/322 reads (14%) | called by mutect2, varscan2
- CCM2L | c.1469T>A p.I490N | Missense Mutation (SNP) | VAF 64/402 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- CCM2L | c.1522A>G p.S508G | Missense Mutation (SNP) | VAF 60/341 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.716); called by muse, varscan2
- DPP6 | c.2357T>A p.I786N (on ENST00000377770 / NM_001364500.2; = p.I724N on NM_001936.5) | Missense Mutation (SNP) | VAF 31/167 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- LAMP5 | c.604A>C p.I202L | Missense Mutation (SNP) | VAF 30/212 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- MAP7D2 | c.1205A>G p.K402R | Missense Mutation (SNP) | VAF 38/212 reads (18%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- RHPN2 | c.1800+3G>T | Splice Region (SNP) | VAF 40/310 reads (13%) | called by muse, mutect2, varscan2
- TBCE | c.338C>G p.T113S | Missense Mutation (SNP) | VAF 54/346 reads (16%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- TFRC | c.1859C>T p.S620L | Missense Mutation (SNP) | VAF 77/427 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, varscan2
- ZNF512B | c.2326A>T p.K776* | Nonsense Mutation (SNP) | VAF 22/214 reads (10%) | called by muse, mutect2
- COL22A1 | c.1689T>G p.G563= | Silent (SNP) | VAF 11/202 reads (5%) | catalogued as rs901674230, COSV57338622; called by muse, mutect2
- HEATR1 | c.6067C>T p.L2023= | Silent (SNP) | VAF 30/252 reads (12%) | called by muse, mutect2
- JAG1 | c.2730G>A p.E910= | Silent (SNP) | VAF 74/438 reads (17%) | called by muse, mutect2, varscan2
- MGAT3 | c.330C>A p.R110= | Silent (SNP) | VAF 14/82 reads (17%) | catalogued as COSV57867851; called by muse, mutect2, varscan2
- SENP5 | c.1596C>T p.V532= | Silent (SNP) | VAF 20/106 reads (19%) | catalogued as COSV60207266; called by muse, mutect2, varscan2
- TAB3 | c.78C>T p.G26= | Silent (SNP) | VAF 40/268 reads (15%) | catalogued as rs763138676, COSV55836801; called by muse, mutect2, varscan2
- WDR13 | c.306C>T p.A102= | Silent (SNP) | VAF 18/108 reads (17%) | called by muse, mutect2, varscan2
- ZNF768 | c.1395C>G p.T465= | Silent (SNP) | VAF 38/211 reads (18%) | called by muse, mutect2, varscan2
- BHLHE22 | chr8:64576356 A>G | 5'Flank (SNP) | VAF 26/284 reads (9%) | called by muse, mutect2
- ERAL1 | chr17:28861418 A>G | 3'Flank (SNP) | VAF 32/219 reads (15%) | called by muse, mutect2, varscan2
- GLRX5 | chr14:95533554 C>A | 5'Flank (SNP) | VAF 34/307 reads (11%) | called by muse, mutect2, varscan2
- NDUFA4 | c.-25C>T | 5'UTR (SNP) | VAF 60/390 reads (15%) | catalogued as rs367837515; called by muse, mutect2, varscan2
